Somatic mutation profile of tumor specimen HCM-BROD-0423-C71-01A (aliquot HCM-BROD-0423-C71-01A-11D-A83U-36) from HCMI case HCM-BROD-0423-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 37.9 years (13,854 days).
Specimen HCM-BROD-0423-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4a72879-2050-491f-b72d-a772d302a2d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0423-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0423-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24e6359c-a5d2-40b2-b980-7bfae4fa4715

The open-access MAF lists 41 somatic variants for this specimen: 27 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 13, Frame Shift Del 2, Nonsense Mutation 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASAP3 | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.758); catalogued as rs199608986, COSV60876072; called by muse, mutect2, varscan2
- EIF2B5 | c.26C>G p.P9R | Missense Mutation (SNP) | VAF 202/612 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.299); catalogued as COSV56605972; called by mutect2, varscan2
- HHIPL2 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 120/300 reads (40%) | catalogued as rs779253171, COSV58563608, COSV58567693; called by muse, mutect2, varscan2
- LMO7 | c.3808A>G p.N1270D (on ENST00000357063; = p.N951D on NM_005358.5) | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs771607927; called by muse, mutect2, varscan2
- OR9H1P | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 127/335 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs1349492735; called by muse, varscan2
- PMCH | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.611); catalogued as COSV59672281; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 42/80 reads (53%) | catalogued as rs146650273; called by pindel, varscan2
- RAMP3 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 218/831 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.337); catalogued as rs778074274, COSV54246431; called by muse, mutect2, varscan2
- RBM27 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 180/698 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.982); catalogued as rs371826086; called by muse, varscan2
- STAG2 | c.2286del p.K763Nfs*3 | Frame Shift Del (DEL) | VAF 50/72 reads (69%) | catalogued as COSV54354371; called by mutect2, pindel, varscan2
- TRPC4 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 103/266 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58993518; called by muse, mutect2, varscan2
- TTLL10 | c.1304A>C p.H435P (on ENST00000379289 / NM_001130045.2; = p.H362P on NM_153254.3) | Missense Mutation (SNP) | VAF 175/428 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs772622013; called by muse, mutect2, varscan2
- AMY1C | c.1057G>C p.V353L | Missense Mutation (SNP) | VAF 66/430 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.161); called by muse, varscan2
- ARHGAP33 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 154/399 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CTNND1 | c.2312C>T p.S771F (on ENST00000399050 / NM_001085458.2; = p.S765F on NM_001331.3) | Missense Mutation (SNP) | VAF 184/726 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- DIS3 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, varscan2
- FZD10 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 277/826 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.175A>C p.K59Q (on ENST00000354667 / NM_031243.3; = p.K47Q on NM_002137.4) | Missense Mutation (SNP) | VAF 150/508 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.045); called by muse, varscan2
- ITGB8 | c.735G>T p.K245N | Missense Mutation (SNP) | VAF 132/545 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- OR52E6 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 125/287 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- OR5D16 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 162/500 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- RENBP | c.773A>G p.H258R | Missense Mutation (SNP) | VAF 129/168 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RYR1 | c.10825-1G>A p.X3609_splice | Splice Site (SNP) | VAF 157/369 reads (43%) | called by muse, mutect2, varscan2
- TMEM236 | c.753G>T p.M251I | Missense Mutation (SNP) | VAF 167/244 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TSKU | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 210/549 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.03); called by mutect2, varscan2
- VWA5B1 | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 15/490 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- ZNF91 | c.719G>C p.C240S | Missense Mutation (SNP) | VAF 120/318 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, varscan2
- ACOXL | c.1740G>A p.P580= (on ENST00000676595; = p.P550= on NM_001142807.4) | Silent (SNP) | VAF 348/913 reads (38%) | called by muse, varscan2
- AJAP1 | c.564C>T p.D188= | Silent (SNP) | VAF 312/818 reads (38%) | catalogued as COSV65453182; called by muse, varscan2
- ERV3-1 | c.828C>T p.F276= | Silent (SNP) | VAF 215/834 reads (26%) | catalogued as rs761270010, COSV104391678; called by muse, varscan2
- FNDC1 | c.774C>T p.D258= | Silent (SNP) | VAF 171/209 reads (82%) | catalogued as rs765767174; called by muse, mutect2, varscan2
- FNIP1 | c.786C>T p.L262= | Silent (SNP) | VAF 232/419 reads (55%) | called by muse, varscan2
- LEXM | c.516G>A p.K172= | Silent (SNP) | VAF 93/271 reads (34%) | called by muse, mutect2, varscan2
- NTN4 | c.495C>T p.S165= | Silent (SNP) | VAF 176/493 reads (36%) | catalogued as rs758912394, COSV100643860; called by muse, varscan2
- SGSM1 | c.2862G>A p.T954= (on ENST00000400359 / NM_001039948.4; = p.T893= on NM_133454.3) | Silent (SNP) | VAF 153/395 reads (39%) | catalogued as rs1038290904, COSV63082825; called by muse, varscan2
- SHANK2 | c.1371C>T p.P457= | Silent (SNP) | VAF 340/912 reads (37%) | catalogued as rs782397098, COSV53612223; ClinVar: likely benign; called by muse, varscan2
- SIK3 | c.1650C>T p.N550= (on ENST00000445177 / NM_001366686.2; = p.N556= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 219/543 reads (40%) | called by muse, mutect2, varscan2
- SOST | c.378A>T p.R126= | Silent (SNP) | VAF 407/1336 reads (30%) | called by muse, varscan2
- TMPRSS9 | c.957C>T p.N319= (on ENST00000648592; = p.N285= on NM_182973.2) | Silent (SNP) | VAF 296/783 reads (38%) | catalogued as rs368841376; called by muse, mutect2, varscan2
- UGT2A3 | c.231C>G p.V77= | Silent (SNP) | VAF 158/453 reads (35%) | called by muse, mutect2, varscan2
- XIRP2 | c.*492A>G | 3'UTR (SNP) | VAF 141/336 reads (42%) | called by muse, mutect2, varscan2
